Surgical pathology report (de-identified scan), TCGA case TCGA-44-A479, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A479-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

ICD-O-3

adenocarcinoma, NOS
8140/3

Site: lung, upper lobe

9-5-12
RD

C34.1

Procedure:

Diagnosis

- A. Lung, right upper lobe, resection:
Adenocarcinoma, poorly differentiated, 3.9 cm.
Surgical margins uninvolved.
2 lymph nodes with no evidence of metastatic disease (0/2).
- B. Lung, "portion of lower lobe", resection:
No evidence of malignancy.
- C. Level 10 lymph nodes, resection:
No evidence of metastasis in 4 lymph nodes (0/4).
- D. R4 lymph nodes, resection:
No evidence of metastasis in two lymph nodes (0/2).
- B. Level 7 lymph nodes, resection:
No evidence of metastasis in 4 lymph nodes (0/4).

Microscopic Description:

Microscopic examination performed.

A. Histologic type: adenocarcinoma
Histologic grade: poorly differentiated
Primary tumor (pT): 3.9 cm, pT2
Margins of resection: negative
Direct extension of tumor: not identified
Venous (large vessel) invasion: not identified
Arterial (large vessel) invasion: not identified
Lymphatic (small vessel) invasion: not identified
Regional lymph nodes (pN): negative, pN0
Distant metastasis (pM): cannot be evaluated by this specimen, pMX
Other findings: none

- B. Sections of the lower lobe demonstrate atelectasis and focal hemorrhage but no evidence of malignancy.
- C. The level 10 lymph node demonstrates no evidence of metastasis in 4 lymph nodes.
- D. The R4 lymph node demonstrates no evidence of metastasis in 2 lymph nodes.
- E. The level 7 lymph node demonstrates no evidence of metastasis in 4 lymph nodes.

Specimen

- A. Right upper lobe
B. Portion of lower lobe
C. Level 10 lymph node
D. R4 lymph node
E. Level 7 lymph node

Clinical Information
Lung cancer

Gross Description

- A. Received fresh for tissue procurement labeled "right upper lobe" is a 14.5 x 11.5 x 4.5 cm lobectomy specimen with attached 1 cm in length, 1.2 x 0.9 cm in diameter bronchial stump. The pleura is smooth to scabrous tan red-gray with an indurated focus along the medial aspect.

[page 2 of 2]
The pleura is inked black and the specimen is sectioned. On sectioning, there is a 3.9 x 3.5 x 3.2 cm rubbery tan-white tumor mass which extends to within 0.3 cm of the inked pleural surface. A portion of tumor and a portion of normal parenchyma are submitted for tissue procurement as requested. The remaining parenchyma is spongiform tan-pink-red without additional mass lesion or abnormality. Two soft gray-black tissues in keeping with lymph nodes measuring up to 0.8 cm are recovered from the hilum. RS 12
Summary: 1 - bronchial stump margin, 2 - vascular margins, 3 - hilar lymph nodes, 4 through 6 - tumor to inked pleural surface, 7 through 9 - tumor to adjacent parenchyma, 10 through 12 - random

B. Received fresh labeled "portion of lower lobe" is a wedge-shaped, 5.4 x 2.7 x 1.3 cm soft portion of lung tissue with a single staple line along one aspect. The staple line is removed and the underlying surface is inked blue. The pleura is slightly scabrous tan-pink. On sectioning, the parenchyma is spongiform tan red without apparent mass lesion or abnormality. AS6

C. Received in formalin labeled "level X lymph node" is a 2.1 x 1.7 x 0.7 cm rubbery tan-gray-pink tissue which is bisected and entirely submitted in one block.

D. Received in formalin labeled "R. 4 lymph node" are 2 slightly fragmented rubbery tan-gray-pink tissues averaging 1 cm in greatest dimension. AS1

E. Received in formalin labeled "level VII lymph node" are 4 slightly rubbery tan-pink to gray-black tissues ranging from 0.4-0.9 cm in greatest dimension. AS1

#229112

Source: NCI Genomic Data Commons file bbcc0491-8315-4d88-8f18-9cb8982de8f5 (TCGA-44-A479.FFCFD93C-1D69-4DF8-9E1B-E2A4EEA66613.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).